Somatic mutation profile of tumor specimen BA2278D (aliquot aq-BA2278D) from BEATAML1.0 case 2457, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute monoblastic and monocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.6 years (17,394 days).
Specimen BA2278D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7a7915e-e9ea-4b1e-a11d-5fe8288d7c9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2625D (Solid Tissue Normal), aliquot aq-BA2625D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b426806-9271-45ad-bd39-8be39260a8b6

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EMILIN1 | c.2726C>A p.A909E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IRGC | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.685); called by muse, mutect2
